Gene-level copy-number profile of tumor specimen C3L-06423-01 from CPTAC case C3L-06423, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 60.2 years (21,996 days).
Specimen C3L-06423-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 5d75ee38-ce75-4192-822e-ed5b7b5d7f26.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-06423-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,227 have no estimate.
https://portal.gdc.cancer.gov/files/86d4f3b4-0d19-4387-8140-c0c0bf09812d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 5,642; copy number 2: 42,243; copy number 3: 8,798; copy number 4: 729; copy number 5: 601; copy number 6: 39; copy number 7: 73; copy number 10: 10; copy number 11: 1; copy number 12: 2; copy number 13: 5; copy number 14: 42; copy number 15: 17; copy number 17: 71; copy number 22: 112; copy number 25: 11.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 983 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–4,175,899, 211 genes, copy number 5 (broad region; genes not listed).
- chr1:22,652,762–25,338,213, 82 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr6:41,736,711–48,068,689, 156 genes, copy number 5–22 (broad region; genes not listed).
- chr7:47,275,154–57,485,895, 186 genes, copy number 7–25 (broad region; genes not listed).
- chr7:63,556,598–63,636,617, 4 genes, copy number 7: SLC29A4P2, TNRC18P2, MIR4283-2, AC006015.1.
- chr7:90,383,721–101,321,823, 284 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr7:101,562,779–103,344,830, 60 genes, copy number 5 (within-gene range 2–5): LINC01007, MYL10, CUX1, AC005096.1, AC005072.1, AC005086.2, AC005086.5, AC005086.4, AC005086.3, AC005086.1, AC005088.1, SH2B2, MIR4285, AC091390.1, Y_RNA, PMS2P12, SPDYE6, PRKRIP1, AC091390.3, AC091390.2, MIR548O, AC073517.1, ORAI2, ALKBH4, LRWD1, MIR5090, MIR4467, POLR2J, RASA4B, POLR2J3, UPK3BL2, AC093668.1, SPDYE2, POLR2J3, RASA4, AC105052.4, AC105052.1, UPK3BL1, AC105052.3, SPDYE2B, POLR2J2, RASA4DP, FAM185A, AC105052.2, FBXL13, RNU6-1136P, RN7SKP198, LRRC17, NFE4, AC073127.1, ARMC10, CRYZP1, NAPEPLD, AC007683.1, RPL23AP95, AC007683.3, DPY19L2P2, S100A11P1, PMPCB, DNAJC2.

Autosomal genes at a single copy (total copy number 1): 4,494. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
